Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEV, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAEV-01A (Primary Tumor).

Department of Pathology

ICD-O 3
Seminoma NOS 9061/3
Site R Testis NOS C62.9
JW 3/13/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.8 cm; no angio-invasion; focal invasion of rete testis; no invasion of tunica albuginea; epididymis and spermatic cord not present in the available slides.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 8269f7ce-1687-431a-bb9b-4f6193819bb5 (TCGA-2G-AAEV-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).